National Lung Screening Trial (NLST) participant 214874 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 60 years; Gender: female; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 120 mA, display field of view 35 cm, reconstruction filter GE Bone / GE Standard.
- T1 (day 341): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 120 mA, display field of view 28 cm, reconstruction filter GE Bone / GE Standard.
- T2 (day 719): Negative screen, significant abnormalities not suspicious for lung cancer. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 100 mA, display field of view 30 cm, reconstruction filter GE Bone / GE Standard.

Abnormalities recorded by the reading radiologist on the CT screens (13 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Benign lung nodule(s) (benign calcification).
- T0 abnormality 2: Emphysema.
- T0 abnormality 3: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T0 abnormality 4: Other potentially significant abnormality below the diaphragm.
- T1 abnormality 1: Emphysema.
- T1 abnormality 2: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T1 abnormality 3: Benign lung nodule(s) (benign calcification).
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 12 mm, longest perpendicular diameter 9 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 26; new (not pre-existing on earlier images).
- T2 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 19 mm, longest perpendicular diameter 11 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 44; new (not pre-existing on earlier images).
- T2 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 16 mm, longest perpendicular diameter 11 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 54; new (not pre-existing on earlier images).
- T2 abnormality 4: Emphysema.
- T2 abnormality 5: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T2 abnormality 6: Benign lung nodule(s) (benign calcification).

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,266.
